Somatic mutation profile of tumor specimen TARGET-10-PARFKD-09A (aliquot TARGET-10-PARFKD-09A-01D) from TARGET case TARGET-10-PARFKD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.1 years (4,064 days).
Specimen TARGET-10-PARFKD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17b4845d-9c0a-407d-b258-4fd3922bfb4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFKD-10A (Blood Derived Normal), aliquot TARGET-10-PARFKD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77642057-5a46-4868-b6c1-4f3f8c09daec

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.434T>G p.F145C | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV57447555, COSV57463059, COSV57463180; called by muse, mutect2, varscan2
- NF1 | c.3143G>A p.W1048* | Nonsense Mutation (SNP) | VAF 10/207 reads (5%) | catalogued as CD1415156; called by muse, mutect2
- PTCH1 | c.3130G>A p.A1044T | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.564); catalogued as rs138458710; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEACAM8 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH2 | c.56C>A p.A19E | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.019); called by muse, mutect2
- EP300 | c.268_269insGACCCCCC p.S90* | Nonsense Mutation (INS) | VAF 41/204 reads (20%) | called by pindel, varscan2
- GIMD1 | c.595T>G p.L199V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MSI1 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PP2D1 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- UGT2A1 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2
- BICC1 | c.1683C>T p.T561= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs759360594, COSV99570322; called by muse, mutect2, varscan2
- FHAD1 | c.2046C>T p.D682= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as rs1352968978; called by muse, mutect2, varscan2
- MYH14 | c.1863C>T p.N621= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as rs374682911; called by muse, mutect2, varscan2
- AL354920.1 | n.602C>A | RNA (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
